Somatic mutation profile of tumor specimen TCGA-56-7222-01A (aliquot TCGA-56-7222-01A-11D-2042-08) from TCGA case TCGA-56-7222, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.5 years (22,097 days).
Specimen TCGA-56-7222-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2c548e3-02ff-473d-9e7e-d73f9b053aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7222-10A (Blood Derived Normal), aliquot TCGA-56-7222-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b738dd2f-9664-4c83-a3b7-768cf685399e

The open-access MAF lists 430 somatic variants for this specimen: 323 protein-altering or splice-affecting, 100 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 100, Nonsense Mutation 21, Frame Shift Del 18, Frame Shift Ins 10, Splice Site 6, In Frame Del 4, RNA 3, Splice Region 2, Intron 2, Translation Start Site 2, Nonstop Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.2682-2A>G p.X894_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as rs1185321132, COSV99648957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 59/71 reads (83%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1322C>T p.A441V (on ENST00000297504 / NM_001282291.2; = p.A424V on NM_007188.5) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99874167; called by muse, mutect2, varscan2
- ABCC8 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs577545383, COSV56849292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABO | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101505951, COSV71743423; called by muse, mutect2, varscan2
- AC098582.1 | c.2511dup p.G838Rfs*23 | Frame Shift Ins (INS) | VAF 18/42 reads (43%) | catalogued as rs774748563; called by mutect2, pindel, varscan2
- AC127029.3 | c.848A>T p.Y283F | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT tolerated (0.62); PolyPhen benign (0.202); catalogued as COSV100033254; called by muse, mutect2, varscan2
- ACVR1 | c.1203G>C p.R401S | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99717686; called by muse, mutect2, varscan2
- ADAMTS20 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239126; called by muse, mutect2, varscan2
- ADAMTS9 | c.4543C>T p.R1515* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV99899174; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as rs1486225120, COSV100389129; called by muse, mutect2, varscan2
- ADGRB2 | c.879G>T p.W293C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as COSV99057130; called by muse, mutect2, varscan2
- AFF3 | c.2462G>T p.R821L | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1405734812, COSV100418507; called by muse, mutect2, varscan2
- AHNAK | c.9881C>G p.S3294C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371629565, COSV57215164; called by muse, mutect2, varscan2
- AJAP1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV100981590; called by muse, mutect2, varscan2
- AKAP17A | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.544); catalogued as COSV100002096; called by muse, mutect2, varscan2
- AMDHD1 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57138648; called by muse, mutect2, varscan2
- AMOT | c.3226G>A p.D1076N (on ENST00000371959 / NM_001113490.1; = p.D667N on NM_133265.3) | Missense Mutation (SNP) | VAF 106/180 reads (59%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.318); catalogued as COSV100494933; called by muse, mutect2, varscan2
- AMY2B | c.856G>T p.G286* | Nonsense Mutation (SNP) | VAF 58/195 reads (30%) | catalogued as COSV100796254; called by muse, mutect2, varscan2
- ANGPT4 | c.1102C>G p.H368D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV101124691; called by muse, mutect2, varscan2
- ANK2 | c.1817A>T p.Y606F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100000844; called by muse, mutect2, varscan2
- ANKRD35 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100841686, COSV62911363; called by muse, mutect2, varscan2
- ANKRD35 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs375339912, COSV62911347; called by muse, mutect2, varscan2
- AP4B1 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56723680; called by muse, mutect2, varscan2
- ARHGAP30 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 92/295 reads (31%) | catalogued as COSV100920191, COSV63519470; called by muse, mutect2, varscan2
- ARHGAP5 | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 30/48 reads (63%) | catalogued as COSV100565173; called by muse, mutect2, varscan2
- ARID4B | c.2062A>C p.K688Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99935377; called by muse, mutect2, varscan2
- ARMC4 | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs773189950, COSV100536578; called by muse, mutect2, varscan2
- ATP10A | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); catalogued as COSV100791065; called by muse, mutect2, varscan2
- B3GALNT1 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100251974; called by muse, mutect2
- BAZ2B | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100600523; called by muse, mutect2, varscan2
- BCL9L | c.3459G>C p.Q1153H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); catalogued as COSV99419013; called by mutect2, varscan2
- BFSP2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as COSV100183676; called by muse, mutect2, varscan2
- BMPR2 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1171279006, COSV101001405; called by muse, mutect2, varscan2
- BRINP3 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.431); catalogued as COSV100818621; called by muse, mutect2
- BSG | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100344689; called by muse, varscan2
- C12orf40 | c.1000A>T p.T334S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV100209893; called by muse, mutect2, varscan2
- C2CD5 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100448618; called by muse, mutect2, varscan2
- CACNA1E | c.3266G>T p.S1089I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100701906; called by muse, mutect2
- CACNA2D1 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100666389; called by muse, mutect2, varscan2
- CADPS | c.3697T>A p.Y1233N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99337218; called by muse, mutect2, varscan2
- CAMSAP3 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99350308; called by muse, mutect2, varscan2
- CARD11 | c.2270-2A>T p.X757_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100829128; called by muse, mutect2, varscan2
- CDC45 | c.492A>G p.I164M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV99596573; called by muse, mutect2, varscan2
- CDH12 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV101202104; called by muse, mutect2, varscan2
- CDH18 | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.26); catalogued as COSV56933164, COSV99933589; called by muse, mutect2, varscan2
- CDH20 | c.1727T>A p.I576K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99404972; called by muse, mutect2, varscan2
- CDH9 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 149/263 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV50290079, COSV99142890; called by muse, mutect2, varscan2
- CELSR3 | c.4114C>G p.L1372V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99373179; called by muse, mutect2, varscan2
- CENPP | c.536A>T p.Y179F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV99364041; called by muse, mutect2, varscan2
- CHORDC1 | c.670-2A>T p.X224_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100271971; called by muse, mutect2, varscan2
- CHST1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs780753667, COSV57325575; called by muse, mutect2, varscan2
- CIART | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV99290230; called by muse, mutect2, varscan2
- CLEC4M | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV99940472; called by muse, mutect2, varscan2
- COL11A1 | c.4910T>A p.V1637D | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615909; called by muse, mutect2, varscan2
- COL12A1 | c.2775G>T p.W925C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59401309; called by muse, mutect2, varscan2
- COL24A1 | c.3952-1G>T p.X1318_splice | Splice Site (SNP) | VAF 35/84 reads (42%) | catalogued as COSV100993133; called by muse, mutect2, varscan2
- COL6A3 | c.3261C>A p.N1087K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99797333; called by muse, mutect2
- CTH | c.473C>G p.T158S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.277); catalogued as COSV100697060; called by mutect2, varscan2
- CTR9 | c.1754A>G p.Q585R | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100797323; called by muse, mutect2, varscan2
- CYP4A11 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100152298; called by muse, mutect2
- CYP4F11 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs369299520; called by muse, mutect2, varscan2
- DAB1 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV59728644, COSV59739802; called by muse, mutect2, varscan2
- DEPDC4 | c.883T>C p.*295Rext*7 | Nonstop Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100147320; called by muse, mutect2, varscan2
- DEPTOR | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.089); catalogued as COSV99638288; called by muse, mutect2, varscan2
- DGAT2L6 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60717487; called by muse, mutect2, varscan2
- DLGAP2 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101421592; called by mutect2, varscan2
- DMD | c.3727C>A p.L1243I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV100819076; called by muse, mutect2, varscan2
- DNAH10 | c.7712G>T p.G2571V (on ENST00000409039; = p.G2510V on NM_207437.3) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292152; called by muse, mutect2, varscan2
- DNAH8 | c.2156T>C p.I719T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544274; called by muse, mutect2, varscan2
- DNAH9 | c.11620T>A p.L3874I | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99305185; called by muse, mutect2, varscan2
- DOCK10 | c.3109C>T p.H1037Y | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); catalogued as rs752115203, COSV51403760, COSV99288764; called by muse, mutect2, varscan2
- DST | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 68/165 reads (41%) | catalogued as rs779381492; called by muse, mutect2, varscan2
- ECPAS | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99397928; called by muse, mutect2, varscan2
- EFHD2 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044340; called by muse, mutect2, varscan2
- EGFLAM | c.1652C>A p.P551H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100380148; called by muse, mutect2, varscan2
- EIF2D | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99662678; called by muse, mutect2
- EPB41L2 | c.340A>C p.K114Q | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV100440495; called by muse, mutect2, varscan2
- ERICH3 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100443922, COSV58612268; called by muse, mutect2
- EYA1 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100379094; called by muse, mutect2, varscan2
- FAM199X | c.969T>G p.S323R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.375); catalogued as COSV100245538; called by muse, mutect2, varscan2
- FCGBP | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs142198641; called by muse, mutect2, varscan2
- FEM1B | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100183596; called by muse, mutect2, varscan2
- FGFR2 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100335957, COSV60660026; called by muse, mutect2, varscan2
- FKBP15 | c.3230A>T p.K1077M | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.076); catalogued as COSV99438547; called by muse, mutect2, varscan2
- FN1 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116782; called by muse, mutect2, varscan2
- FSTL5 | c.2347A>T p.K783* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV100054059; called by muse, mutect2, varscan2
- FUT1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038088; called by muse, mutect2, varscan2
- FUT3 | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV54604835, COSV99744465; called by muse, mutect2, varscan2
- GABRA5 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164990, COSV100164994; called by muse, mutect2, varscan2
- GABRR3 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.258); catalogued as rs141112061, COSV72115930; called by muse, mutect2, varscan2
- GDF3 | c.1019T>A p.L340H | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325215; called by muse, mutect2, varscan2
- GIPC1 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV100600048; called by muse, mutect2, varscan2
- GNAS | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100006091; called by muse, mutect2, varscan2
- GON7 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 65/94 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV99184216; called by muse, mutect2, varscan2
- GPALPP1 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100689176; called by muse, mutect2, varscan2
- GPR65 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV99965993; called by muse, mutect2, varscan2
- GRIN3A | c.1959G>T p.L653F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV100701446; called by muse, mutect2, varscan2
- GRM8 | c.1548C>G p.C516W | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281921, COSV100283381; called by muse, mutect2, varscan2
- H2AC14 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100297551; called by muse, mutect2, varscan2
- H4C1 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.59); catalogued as COSV99771983; called by muse, mutect2, varscan2
- HCN1 | c.1649C>A p.T550N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100299636; called by muse, mutect2, varscan2
- HECW1 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV101223218; called by muse, mutect2, varscan2
- HFM1 | c.3931C>T p.L1311F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV99645801; called by muse, mutect2, varscan2
- HIBCH | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1049796593, COSV100675966; called by muse, varscan2
- HID1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100585974; called by muse, mutect2, varscan2
- HIF1A | c.2416A>G p.I806V | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1258843938, COSV100048716; called by muse, mutect2, varscan2
- HSPH1 | c.1916A>G p.E639G | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184828; called by muse, mutect2, varscan2
- HTR1A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV100109018; called by muse, mutect2, varscan2
- IBTK | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100090482; called by muse, mutect2, varscan2
- IFNL3 | c.281T>A p.L94* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101308013; called by muse, mutect2, varscan2
- IGSF10 | c.3314T>A p.L1105Q | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.459); catalogued as COSV99177518; called by muse, mutect2, varscan2
- INPPL1 | c.3566A>C p.Q1189P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as rs1369263812, COSV99996088; called by muse, mutect2, varscan2
- IQGAP3 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV100752109; called by muse, mutect2, varscan2
- ITGBL1 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101095234; called by muse, mutect2, varscan2
- KANSL1 | c.2269G>C p.V757L | Missense Mutation (SNP) | VAF 66/87 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV99294336; called by muse, mutect2, varscan2
- KATNIP | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99850629; called by muse, mutect2, varscan2
- KATNIP | c.582G>T p.R194S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV55192119, COSV99850635; called by muse, mutect2, varscan2
- KBTBD12 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100675399; called by muse, mutect2, varscan2
- KCNA2 | c.324A>G p.I108M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs765790719, COSV100315902; called by muse, mutect2, varscan2
- KCNJ3 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.038); catalogued as rs868028816, COSV99715551; called by muse, mutect2, varscan2
- KCNV2 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs104894116, CM062795, COSV101172556; called by muse, varscan2
- KIFC1 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100997092; called by muse, mutect2, varscan2
- KLHL2 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV99899849; called by muse, mutect2, varscan2
- KLHL3 | c.1139T>C p.M380T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs76353355, COSV100553073; called by muse, mutect2, varscan2
- KMT2C | c.13141G>A p.E4381K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV51518310; called by muse, mutect2, varscan2
- KMT2D | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99979775; called by muse, mutect2, varscan2
- KREMEN1 | c.110G>T p.G37V (on ENST00000407188; = p.G39V on NM_032045.5) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588644; called by muse, mutect2, varscan2
- KRT24 | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 68/110 reads (62%) | catalogued as COSV52879612; called by muse, mutect2, varscan2
- KRTAP19-4 | c.253T>A p.*85Rext*? | Nonstop Mutation (SNP) | VAF 44/81 reads (54%) | catalogued as COSV100478440; called by muse, mutect2, varscan2
- LAMA2 | c.2245A>G p.I749V | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101370332; called by mutect2, varscan2
- LAMB4 | c.1335C>A p.S445R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV52729904, COSV99223561; called by muse, mutect2, varscan2
- LEMD3 | c.2215G>T p.G739C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384259; called by muse, mutect2, varscan2
- LRP1B | c.1998A>T p.E666D | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101255039, COSV67254142; called by muse, mutect2, varscan2
- LRP1B | c.1410C>G p.V470= | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101255040, COSV67281780; called by muse, mutect2
- LRRC2 | c.989T>G p.I330R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99947327; called by muse, varscan2
- MAGI3 | c.1901A>G p.Q634R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1315360837, COSV100288611; called by muse, mutect2, varscan2
- MAP3K19 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV100208377; called by muse, mutect2, varscan2
- MDN1 | c.13736C>T p.S4579F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1171052563, COSV101021068; called by muse, mutect2, varscan2
- MMP16 | c.1058T>G p.L353R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54163657, COSV99688354; called by muse, mutect2, varscan2
- MOCS1 | c.1330T>C p.S444P | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1342906697, COSV99225270; called by muse, mutect2, varscan2
- MORF4L1 | c.494C>A p.T165N (on ENST00000331268 / NM_206839.2; = p.T126N on NM_006791.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.392); catalogued as COSV100489070; called by muse, mutect2, varscan2
- MPHOSPH6 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1457073069, COSV50736819, COSV99259149; called by muse, mutect2, varscan2
- MRPL20 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV100784959; called by muse, mutect2, varscan2
- MTHFD1 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99386740; called by muse, mutect2, varscan2
- MTOR | c.2897A>G p.H966R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100815935; called by muse, mutect2, varscan2
- MUC17 | c.4847C>A p.A1616D | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as COSV100072633; called by muse, mutect2, varscan2
- MUC5AC | c.16831G>A p.E5611K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.861); catalogued as COSV100611396; called by mutect2, varscan2
- MUTYH | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100587994; called by muse, mutect2, varscan2
- MUTYH | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100587995; called by muse, mutect2, varscan2
- MYBPC1 | c.1168C>G p.R390G (on ENST00000550270 / NM_206820.2; = p.R415G on NM_002465.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100637875; called by muse, mutect2, varscan2
- MYBPC2 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748773939, COSV100731738; called by muse, mutect2, varscan2
- MYCBP2 | c.5713A>T p.S1905C (on ENST00000357337; = p.S1943C on NM_015057.5) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV100629825; called by muse, mutect2, varscan2
- MYO1G | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140521361; called by muse, mutect2, varscan2
- MYPN | c.1753C>A p.H585N | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV100589801; called by muse, mutect2, varscan2
- NAB1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100492937; called by muse, mutect2, varscan2
- NAT8L | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100526904; called by mutect2, varscan2
- NAV3 | c.6805A>G p.I2269V (on ENST00000397909 / NM_001024383.2; = p.I2247V on NM_014903.6) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57060910, COSV99889243; called by muse, mutect2
- NCOA5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV99275416; called by muse, mutect2, varscan2
- NCSTN | c.1944G>T p.W648C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667010; called by muse, mutect2, varscan2
- NEB | c.19642_19643insC p.G6548Afs*3 | Frame Shift Ins (INS) | VAF 15/30 reads (50%) | catalogued as COSV99419432; called by mutect2, pindel, varscan2
- NEU2 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV99290511; called by muse, mutect2, varscan2
- NF1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 26/42 reads (62%) | catalogued as CM042439, COSV62194407, COSV62202465; called by muse, mutect2, varscan2
- NLRP12 | c.1340C>A p.P447Q | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV100145099; called by muse, mutect2, varscan2
- NPVF | c.193T>A p.W65R | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99760202; called by muse, mutect2, varscan2
- NRDC | c.2018A>T p.Q673L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs762722640, COSV100703273, COSV100704077; called by muse, mutect2, varscan2
- NRN1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs753009654, COSV55206030; called by muse, mutect2, varscan2
- NSD1 | c.5296C>T p.R1766* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as CM052311, COSV100728748; called by muse, mutect2, varscan2
- NTRK2 | c.2210G>A p.W737* (on ENST00000323115 / NM_001369534.1; = p.W753* on NM_006180.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 71/113 reads (63%) | catalogued as COSV99454292; called by muse, mutect2, varscan2
- NXPE1 | c.1200dup p.H401Tfs*2 (on ENST00000424269; = p.H259Tfs*2 on NM_152315.5) | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as rs768846260; called by mutect2, pindel
- OBSCN | c.4835G>T p.R1612L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV99475998; called by muse, mutect2, varscan2
- OBSCN | c.8098A>G p.T2700A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.76); catalogued as COSV99476001; called by muse, mutect2, varscan2
- OOSP2 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1394183199, COSV99613331; called by muse, mutect2, varscan2
- OR10Q1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1554976493, COSV57469961; called by muse, mutect2, varscan2
- OR14C36 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58602136, COSV58603027; called by muse, mutect2, varscan2
- OR14I1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs759332854, COSV100700462; called by muse, mutect2, varscan2
- OR1J2 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV100093181; called by muse, mutect2, varscan2
- OR4M1 | c.16T>G p.Y6D | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100271089; called by muse, mutect2, varscan2
- OR6F1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV57469003; called by muse, mutect2, varscan2
- OR9G4 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV100265083; called by muse, mutect2, varscan2
- OTUD7B | c.1042T>C p.S348P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967459; called by muse, mutect2, varscan2
- PAPOLA | c.842G>T p.W281L | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99354120; called by muse, mutect2, varscan2
- PAPPA | c.4429C>T p.Q1477* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100073552; called by muse, mutect2, varscan2
- PARD3B | c.2135A>C p.D712A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100592969; called by muse, mutect2, varscan2
- PCDH11X | c.4037C>A p.P1346H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV100010679; called by muse, mutect2
- PCDHGB2 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99535137; called by muse, mutect2, varscan2
- PDGFA | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100627292, COSV63279803; called by muse, mutect2
- PDZD2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs1396977489, COSV99224546; called by muse, mutect2, varscan2
- PDZD2 | c.3581C>G p.T1194S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV99224547; called by muse, mutect2, varscan2
- PDZRN3 | c.2369G>T p.S790I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99728794; called by muse, mutect2, varscan2
- PIK3CG | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100782773; called by muse, mutect2, varscan2
- PITPNB | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100086714; called by muse, mutect2, varscan2
- PKHD1 | c.6502C>A p.H2168N | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100582392; called by muse, mutect2, varscan2
- PLCB1 | c.2813A>G p.H938R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.39); catalogued as COSV100570217; called by muse, mutect2, varscan2
- PLSCR1 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs745943253, COSV100678345; called by muse, mutect2, varscan2
- POLR1A | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.156); catalogued as COSV99807411; called by muse, mutect2, varscan2
- PPFIA1 | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1025987592, COSV99557223; called by muse, mutect2, varscan2
- PPP3R1 | c.446C>G p.S149C | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs778295413, COSV99310267; called by muse, mutect2, varscan2
- PREP | c.398G>T p.G133V (on ENST00000369110; = p.G199V on NM_002726.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100963834; called by muse, mutect2, varscan2
- PRICKLE2 | c.1052G>T p.R351L (on ENST00000295902; = p.R295L on NM_198859.4) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as COSV99896811, COSV99897007; called by muse, mutect2, varscan2
- PRKCB | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV100333236, COSV57773104; called by muse, mutect2, varscan2
- PTEN | c.668del p.K223Rfs*33 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | catalogued as COSV64294566; called by mutect2, pindel, varscan2
- PTGFRN | c.1837G>T p.V613L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV101277305; called by muse, mutect2, varscan2
- PTP4A1 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101037818; called by muse, mutect2, varscan2
- PTPRJ | c.2722G>T p.V908F | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs763699928, COSV101394823; called by muse, mutect2, varscan2
- PXDN | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs372430177, COSV99413016; called by muse, mutect2, varscan2
- PXDNL | c.2503G>A p.V835I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV100682924; called by muse, mutect2, varscan2
- RABGGTB | c.56T>C p.L19S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV100175005; called by muse, mutect2, varscan2
- RASA1 | c.3017C>G p.S1006* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as COSV56925103, COSV99169814; called by muse, mutect2, varscan2
- RBM26 | c.1664G>T p.R555L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs371759116, COSV99936020; called by muse, mutect2, varscan2
- RETN | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV99679382; called by muse, mutect2, varscan2
- RFX6 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM137631, COSV100263575; called by muse, mutect2, varscan2
- RHPN2 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as rs1308048021, COSV99577352; called by muse, mutect2, varscan2
- RNF113B | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV99940308; called by muse, mutect2, varscan2
- RNF113B | c.210C>A p.H70Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV99940309; called by muse, mutect2, varscan2
- ROBO1 | c.3104C>G p.S1035* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV71393020; called by muse, mutect2
- ROBO3 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101184990, COSV67301861; called by muse, mutect2, varscan2
- RSAD2 | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.524); catalogued as COSV101149817; called by muse, mutect2, varscan2
- RYR2 | c.12244G>C p.E4082Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs774241742, COSV100769329; ClinVar: uncertain significance; called by muse, varscan2
- SAP130 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.275); catalogued as COSV99384487; called by muse, mutect2, varscan2
- SCN11A | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100181277, COSV56567381; called by muse, mutect2, varscan2
- SCN1A | c.3341C>T p.T1114I (on ENST00000303395 / NM_001202435.3; = p.T1103I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV100319045; called by muse, mutect2, varscan2
- SCN2A | c.159C>A p.N53K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV51858297; called by muse, mutect2, varscan2
- SCN2A | c.474G>T p.V158= | Splice Region (SNP) | VAF 70/150 reads (47%) | catalogued as COSV99330986; called by muse, mutect2, varscan2
- SCRN3 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99767193; called by muse, mutect2, varscan2
- SDSL | c.422del p.P141Rfs*6 | Frame Shift Del (DEL) | VAF 36/153 reads (24%) | catalogued as rs752093894; called by mutect2, pindel, varscan2
- SHANK2 | c.3664G>A p.A1222T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555153741, COSV53600959, COSV99573203; called by muse, mutect2, varscan2
- SHOX | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61860481; called by muse, mutect2, varscan2
- SIGIRR | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100229917; called by muse, mutect2, varscan2
- SKP2 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 52/530 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as COSV99947981; called by muse, mutect2
- SLC12A2 | c.781A>G p.N261D | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.845); catalogued as COSV99320896; called by muse, mutect2, varscan2
- SLC12A3 | c.1314C>A p.Y438* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99344028; called by muse, mutect2, varscan2
- SLC22A25 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as COSV100123537, COSV100123843; called by muse, mutect2, varscan2
- SLC38A6 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV99959616, COSV99959926; called by muse, mutect2, varscan2
- SLC38A8 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100230401; called by muse, mutect2, varscan2
- SLC6A15 | c.619T>A p.W207R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99880531; called by muse, mutect2, varscan2
- SOGA3 | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100846860; called by muse, mutect2, varscan2
- SPATA31E1 | c.2675C>A p.P892H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV100350222; called by muse, mutect2, varscan2
- SPTBN4 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs749627882, COSV58946877; called by muse, mutect2, varscan2
- SRPK3 | c.1462A>C p.I488L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99473073; called by muse, mutect2
- STRN | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV99815147; called by muse, mutect2, varscan2
- SULT1C2 | c.24del p.K9Nfs*3 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV52264983; called by pindel, varscan2
- SUPT16H | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99359777; called by muse, mutect2, varscan2
- SYBU | c.1264G>T p.G422W (on ENST00000276646 / NM_001099754.2; = p.G421W on NM_017786.6) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99405951; called by muse, mutect2, varscan2
- SYNE1 | c.18103G>C p.A6035P (on ENST00000367255 / NM_182961.4; = p.A5964P on NM_033071.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV99559333; called by muse, mutect2, varscan2
- TAF1L | c.1994dup p.A666Gfs*38 | Frame Shift Ins (INS) | VAF 28/62 reads (45%) | catalogued as rs760628590; called by mutect2, varscan2
- TAL1 | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99595977; called by muse, mutect2, varscan2
- TBC1D8 | c.637A>C p.N213H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100964378; called by muse, mutect2, varscan2
- TCERG1 | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99694664; called by muse, mutect2, varscan2
- TET1 | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV101017897; called by muse, mutect2, varscan2
- THSD7B | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.681); catalogued as COSV99747957; called by mutect2, varscan2
- TIAM1 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99734230; called by muse, mutect2, varscan2
- TIAM1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV99734233; called by muse, mutect2, varscan2
- TMEM132A | c.1819G>A p.G607S (on ENST00000453848 / NM_178031.3; = p.G608S on NM_017870.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335624739, COSV50008343; called by muse, mutect2, varscan2
- TNK1 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV100294811; called by muse, mutect2, varscan2
- TNXB | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100926156; called by muse, mutect2, varscan2
- TRAPPC12 | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100160349; called by muse, mutect2
- TRIM58 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63569133, COSV63572103; called by muse, mutect2, varscan2
- TRIM6 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99546290; called by muse, mutect2, varscan2
- TRIM67 | c.2280C>A p.N760K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs760413176, COSV100792093; called by muse, mutect2, varscan2
- TRIP12 | c.5783G>T p.G1928V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389860; called by muse, mutect2
- TRPV6 | c.920A>T p.Q307L | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV100844235; called by muse, mutect2
- TTC29 | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV100283525; called by muse, mutect2, varscan2
- TTN | c.91453T>C p.W30485R (on ENST00000591111; = p.W23061R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | PolyPhen probably damaging (1); catalogued as COSV100604336; called by muse, mutect2, varscan2
- TTN | c.78142G>C p.A26048P (on ENST00000591111; = p.A18624P on NM_003319.4) | Missense Mutation (SNP) | VAF 20/195 reads (10%) | PolyPhen probably damaging (0.999); catalogued as COSV100604339; called by muse, mutect2, varscan2
- TTN | c.53884C>T p.P17962S (on ENST00000591111; = p.P10538S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV100604345; called by muse, mutect2, varscan2
- TTN | c.48202G>C p.E16068Q (on ENST00000591111; = p.E8644Q on NM_003319.4) | Missense Mutation (SNP) | VAF 277/505 reads (55%) | PolyPhen possibly damaging (0.743); catalogued as COSV100604364, COSV60004341; called by muse, mutect2, varscan2
- TTN | c.17339C>T p.A5780V (on ENST00000591111; = p.A4853V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | PolyPhen benign (0.009); catalogued as rs758663081, COSV100604370; called by muse, mutect2, varscan2
- UBQLN3 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs1254918664, COSV100293533; called by muse, mutect2, varscan2
- VCX3A | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV101129848; called by muse, varscan2
- WASHC5 | c.2025G>T p.K675N | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100572733; called by muse, mutect2, varscan2
- XIRP2 | c.1773T>A p.D591E (on ENST00000628543; = p.D766E on NM_152381.6) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99741192; called by muse, mutect2, varscan2
- XKR7 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); catalogued as rs1185389840, COSV101629246; called by muse, mutect2, varscan2
- ZBTB16 | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.407); catalogued as rs779616803, COSV100251278, COSV60096432; called by muse, mutect2, varscan2
- ZC3H3 | c.2614G>T p.A872S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs761197045, COSV99367671; called by muse, mutect2, varscan2
- ZFP14 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99525099; called by mutect2, varscan2
- ZKSCAN8 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV100362862; called by muse, mutect2, varscan2
- ZNF142 | c.3843T>A p.N1281K (on ENST00000411696 / NM_001379660.1; = p.N1081K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV101376917; called by muse, mutect2, varscan2
- ZNF234 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV101468351; called by muse, mutect2, varscan2
- ZNF276 | c.671A>C p.Y224S (on ENST00000443381 / NM_001113525.2; = p.Y149S on NM_152287.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.997); catalogued as COSV99234766; called by muse, mutect2, varscan2
- ZNF33A | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100275657; called by muse, mutect2, varscan2
- ZNF423 | c.3418G>A p.A1140T (on ENST00000563137 / NM_001379286.1; = p.A1132T on NM_015069.4) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV99280925; called by muse, mutect2, varscan2
- ZNF468 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99700460; called by muse, mutect2
- ZNF507 | c.2543A>T p.E848V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV100321731; called by muse, mutect2, varscan2
- ZNF662 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100066206; called by muse, mutect2, varscan2
- ZNF681 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV101267433, COSV68073531; called by muse, mutect2, varscan2
- ZP3 | c.1010C>T p.P337L (on ENST00000394857 / NM_001110354.2; = p.P286L on NM_007155.6) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60631672; called by muse, mutect2, varscan2
- ZW10 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99562588; called by muse, mutect2, varscan2
- ABR | c.2189A>T p.E730V (on ENST00000302538 / NM_021962.5; = p.E693V on NM_001092.5) | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- AMBRA1 | c.396del p.W132Cfs*22 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel
- AP5Z1 | c.408del p.L137Yfs*82 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- BRINP1 | c.901del p.Y301Ifs*14 | Frame Shift Del (DEL) | VAF 45/127 reads (35%) | called by mutect2, pindel, varscan2
- CCDC102A | c.715del p.W239Gfs*14 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- CCDC148 | c.939dup p.A314Cfs*14 | Frame Shift Ins (INS) | VAF 28/65 reads (43%) | called by mutect2, pindel, varscan2
- DCDC1 | c.4880del p.I1627Kfs*18 (on ENST00000597505 / NM_001367979.1; = p.I734Kfs*18 on NM_020869.3) | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- DNAH5 | c.9849del p.K3283Nfs*9 | Frame Shift Del (DEL) | VAF 66/342 reads (19%) | called by mutect2, pindel, varscan2
- DNAJB1 | c.756_791del p.D253_E264del | In Frame Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- GOLGA6B | c.1831_1842del p.L611_V614del | In Frame Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- HMCN1 | c.14296_14320del p.W4766Tfs*87 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- HOXA3 | c.1168dup p.H390Pfs*130 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- IGHV7-81 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 88/147 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IGKV1-12 | c.64T>A p.C22S | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, varscan2
- IGKV1-12 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- IGKV1D-42 | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- LRRC37B | c.23dup p.W10Mfs*31 | Frame Shift Ins (INS) | VAF 66/131 reads (50%) | called by mutect2, pindel, varscan2
- MED18 | c.531_569del p.G178_A190del | In Frame Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel
- MRGPRX4 | c.674_682del p.F225_L227del | In Frame Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- NPY5R | c.740del p.N247Tfs*8 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- OR5D16 | c.855dup p.L287Vfs*11 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- PGM3 | c.205-3_228del p.X69_splice | Splice Site (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- PPP1R3A | c.3327del p.W1110Gfs*22 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.2106dup p.A703Cfs*9 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- SENP7 | c.2048del p.C683Ffs*13 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- SLCO2B1 | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SMARCC2 | c.2693del p.K898Sfs*42 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- SORL1 | c.2060del p.G687Vfs*4 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- TAF4 | c.2969_2970+1del p.X990_splice | Splice Site (DEL) | VAF 21/51 reads (41%) | called by pindel, varscan2
- TCTE1 | c.1431_1438del p.R478Gfs*17 | Frame Shift Del (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- TRAV39 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- USP49 | c.271dup p.D91Gfs*34 | Frame Shift Ins (INS) | VAF 51/157 reads (32%) | called by mutect2, pindel, varscan2
- USP6NL | c.1672del p.E558Sfs*62 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | called by mutect2, pindel, varscan2
- ZNF286A | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF80 | c.304del p.E102Rfs*52 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- A1CF | c.996C>A p.G332= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV99255715; called by muse, mutect2, varscan2
- ABCA3 | c.1965G>A p.E655= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as rs1394640180, COSV100068278, COSV57060337; called by muse, mutect2, varscan2
- ADGRV1 | c.1053A>C p.I351= | Silent (SNP) | VAF 61/108 reads (56%) | catalogued as COSV101315725; called by muse, mutect2, varscan2
- AHNAK2 | c.11991G>A p.K3997= | Silent (SNP) | VAF 175/283 reads (62%) | catalogued as COSV100316845; called by muse, mutect2, varscan2
- ARHGAP25 | c.561C>T p.F187= (on ENST00000409202 / NM_001007231.3; = p.F179= on NM_014882.3) | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs150575126; called by muse, mutect2, varscan2
- ASH1L | c.8184A>G p.T2728= (on ENST00000368346 / NM_001366177.2; = p.T2723= on NM_018489.3) | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100853308; called by muse, mutect2, varscan2
- CCDC141 | c.4269T>C p.G1423= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV99836542; called by muse, mutect2, varscan2
- CCDC6 | c.642T>G p.V214= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV99569335; called by muse, mutect2, varscan2
- CDHR2 | c.3663C>G p.P1221= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99991364; called by muse, mutect2, varscan2
- CELSR2 | c.6705A>T p.R2235= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99603536; called by muse, mutect2, varscan2
- CNTN1 | c.1203T>C p.Y401= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100751195; called by muse, mutect2, varscan2
- CNTNAP5 | c.2709G>A p.E903= | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs779213534, COSV101443317; called by muse, mutect2, varscan2
- COL24A1 | c.1293C>T p.S431= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1026417483, COSV100993134; called by muse, mutect2
- COL5A3 | c.3468G>T p.P1156= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs139846355, COSV99318521; called by muse, mutect2, varscan2
- CPSF4 | c.63G>A p.Q21= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV99462249; called by muse, mutect2, varscan2
- CPT1B | c.207A>G p.T69= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100376584; called by muse, mutect2, varscan2
- CSE1L | c.898T>C p.L300= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99521948; called by muse, mutect2, varscan2
- CYP4F22 | c.828T>A p.T276= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV99512695; called by muse, mutect2, varscan2
- CYP4Z1 | c.135G>T p.L45= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV100497587; called by muse, mutect2, varscan2
- DCDC2 | c.1275G>T p.L425= | Silent (SNP) | VAF 109/243 reads (45%) | catalogued as rs534996877, COSV101015338; called by muse, mutect2, varscan2
- DDB1 | c.195G>A p.E65= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100074466; called by muse, mutect2, varscan2
- DHX16 | c.786G>C p.L262= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100905172; called by muse, mutect2, varscan2
- DMKN | c.48G>T p.L16= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100303467; called by muse, mutect2, varscan2
- DYSF | c.273C>G p.V91= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV99245871; called by muse, mutect2, varscan2
- EAF2 | c.480A>G p.E160= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99877440; called by muse, mutect2, varscan2
- EGFLAM | c.1653C>A p.P551= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100379829; called by muse, mutect2, varscan2
- EPB41L3 | c.3252T>C p.D1084= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV100548635; called by muse, mutect2, varscan2
- EPRS1 | c.1671A>G p.A557= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100859352; called by muse, mutect2
- EPYC | c.132C>T p.Y44= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99664581; called by muse, mutect2, varscan2
- FLRT3 | c.1728A>T p.A576= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as COSV99429730; called by muse, mutect2, varscan2
- GABRQ | c.1197C>T p.L399= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as COSV100941192; called by muse, mutect2, varscan2
- GALNT13 | c.1543C>A p.R515= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV101222521; called by muse, mutect2, varscan2
- HEPH | c.3345T>A p.I1115= (on ENST00000343002; = p.I848= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV57959039; called by muse, mutect2, varscan2
- HHIPL1 | c.741C>T p.D247= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs144732406; called by muse, mutect2, varscan2
- HTR3C | c.426C>A p.A142= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as COSV100570549; called by muse, mutect2
- IGHV3-74 | c.147T>C p.S49= | Silent (SNP) | VAF 87/133 reads (65%) | catalogued as rs1207584769; called by muse, mutect2, varscan2
- IGHV4-28 | c.30G>C p.L10= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- KCNK9 | c.669T>C p.F223= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs746229241, COSV100270732; called by muse, mutect2, varscan2
- KIFAP3 | c.492T>C p.D164= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100846854; called by muse, mutect2, varscan2
- KLHL6 | c.1692C>A p.G564= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100384495, COSV58067762; called by muse, mutect2
- LAMA2 | c.963C>T p.C321= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV101370331, COSV101370628; called by muse, mutect2, varscan2
- LPO | c.27C>T p.A9= | Silent (SNP) | VAF 10/305 reads (3%) | catalogued as COSV99228636; called by muse, mutect2
- LRFN2 | c.1342C>A p.R448= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1338608982, COSV100599388, COSV57824249; called by muse, mutect2, varscan2
- LRIF1 | c.174A>T p.L58= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100870823, COSV100870913; called by muse, mutect2, varscan2
- LRRC14B | c.1545G>A p.*515= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99722938; called by muse, mutect2
- LRRC30 | c.228C>G p.L76= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV101274393; called by muse, mutect2, varscan2
- LRRCC1 | c.564C>G p.L188= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100835383; called by muse, mutect2, varscan2
- LRRK1 | c.4872A>T p.P1624= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV99438945; called by muse, mutect2, varscan2
- LRRTM4 | c.225G>A p.K75= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs1181255993, COSV69138944; called by muse, mutect2, varscan2
- MAP3K15 | c.789G>A p.L263= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as COSV100134512; called by muse, mutect2, varscan2
- MATN2 | c.651C>T p.F217= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99646055; called by muse, mutect2, varscan2
- NALCN | c.3384G>T p.V1128= | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as COSV51963395, COSV99214150; called by muse, mutect2
- NDST4 | c.1263A>T p.P421= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99996084; called by muse, mutect2, varscan2
- NEK10 | c.3204C>T p.L1068= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99834994; called by muse, mutect2, varscan2
- NKRF | c.1536A>G p.K512= | Silent (SNP) | VAF 70/97 reads (72%) | catalogued as COSV100441530; called by muse, mutect2, varscan2
- NLRP12 | c.1341G>T p.P447= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV100144812, COSV60751991; called by muse, mutect2, varscan2
- NME8 | c.342C>T p.I114= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs199734697, COSV52247893; called by muse, mutect2, varscan2
- NOA1 | c.1305C>T p.V435= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs201115401, COSV99950474; called by muse, mutect2, varscan2
- NPBWR2 | c.435G>A p.V145= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100871107; called by muse, mutect2, varscan2
- OR10A7 | c.564C>A p.V188= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100406540; called by muse, mutect2, varscan2
- OR10V1 | c.582C>A p.R194= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100275759; called by muse, mutect2, varscan2
- OR1J2 | c.174C>A p.P58= | Silent (SNP) | VAF 71/152 reads (47%) | catalogued as COSV100093178; called by muse, mutect2, varscan2
- OR4D10 | c.330G>A p.V110= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs747345621, COSV101597004; called by muse, mutect2, varscan2
- OR5D14 | c.690C>A p.I230= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100162282, COSV59457621; called by muse, mutect2
- OR6C74 | c.381C>A p.P127= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV100667630, COSV100667716; called by muse, mutect2, varscan2
- OR8B12 | c.228C>A p.I76= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100172738, COSV60911594, COSV60912162; called by muse, mutect2, varscan2
- OXGR1 | c.42C>T p.F14= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53659054; called by muse, mutect2, varscan2
- PCDH10 | c.1638G>T p.R546= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV52105442, COSV99992766; called by muse, mutect2
- PCDHGB3 | c.1494G>A p.P498= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1464333099, COSV53901811; called by muse, mutect2, varscan2
- PEX5L | c.300C>A p.S100= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV55842356, COSV55859291; called by muse, mutect2, varscan2
- PKHD1L1 | c.12276A>G p.A4092= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV101005903; called by muse, mutect2, varscan2
- POPDC3 | c.552T>C p.P184= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99633585; called by muse, mutect2, varscan2
- PPM1L | c.504C>T p.I168= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99861522; called by muse, mutect2, varscan2
- PPP1R12B | c.1659C>T p.Y553= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100406949; called by muse, mutect2, varscan2
- PRPF3 | c.837T>C p.P279= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100254690; called by muse, mutect2, varscan2
- PZP | c.657C>T p.T219= | Silent (SNP) | VAF 25/214 reads (12%) | catalogued as rs140804144; called by muse, mutect2, varscan2
- RBM47 | c.1416A>G p.T472= (on ENST00000295971 / NM_001098634.2; = p.T403= on NM_019027.4) | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV99920532; called by muse, mutect2, varscan2
- RHOXF2 | c.261C>A p.G87= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV101002761; called by muse, mutect2, varscan2
- RIT1 | c.498A>G p.A166= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100851167; called by muse, mutect2, varscan2
- RXRG | c.1380G>T p.L460= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100717405; called by muse, mutect2, varscan2
- RYR2 | c.5868A>C p.A1956= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV63716180; called by muse, mutect2, varscan2
- SCN1A | c.2451G>C p.L817= (on ENST00000303395 / NM_001202435.3; = p.L806= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1304400552, COSV100319988, COSV57672760, COSV57674026; called by muse, mutect2, varscan2
- SCUBE3 | c.2370T>C p.F790= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV99234279; called by muse, mutect2, varscan2
- SEC16B | c.1935G>A p.Q645= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100381456, COSV57625124; called by muse, mutect2, varscan2
- SEMA6D | c.3171C>A p.S1057= (on ENST00000316364 / NM_153618.2; = p.S995= on NM_020858.2) | Silent (SNP) | VAF 128/297 reads (43%) | catalogued as COSV100316760; called by muse, mutect2, varscan2
- SERPINE2 | c.285C>A p.I95= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV99296584; called by muse, mutect2, varscan2
- SHROOM4 | c.1704T>C p.G568= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99173223; called by muse, mutect2, varscan2
- SLC10A2 | c.726T>C p.F242= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99807834; called by mutect2, varscan2
- SLC17A4 | c.1011G>A p.P337= | Silent (SNP) | VAF 59/266 reads (22%) | catalogued as rs138073751; called by muse, mutect2, varscan2
- SMAD9 | c.1116C>T p.T372= (on ENST00000379826 / NM_001127217.3; = p.T335= on NM_005905.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1266417138, COSV100614572; called by muse, mutect2, varscan2
- SUPT20H | c.597C>T p.L199= (on ENST00000350612 / NM_001014286.3; = p.L200= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100634630; called by muse, mutect2, varscan2
- TCOF1 | c.1932C>T p.C644= (on ENST00000377797 / NM_001135243.1; = p.C567= on NM_000356.4) | Silent (SNP) | VAF 90/147 reads (61%) | catalogued as COSV60348959; called by muse, mutect2, varscan2
- TELO2 | c.1812C>T p.Y604= | Silent (SNP) | VAF 50/208 reads (24%) | catalogued as rs1327436040, COSV99248183; called by muse, mutect2, varscan2
- TERF1 | c.1134A>G p.R378= (on ENST00000276603 / NM_017489.3; = p.R358= on NM_003218.4) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs371945488; called by muse, mutect2, varscan2
- TOM1L2 | c.1434C>T p.P478= (on ENST00000379504 / NM_001350333.2; = p.P428= on NM_001033551.3) | Silent (SNP) | VAF 65/91 reads (71%) | catalogued as rs778516125, COSV100540984; called by muse, mutect2, varscan2
- TRAV39 | c.213A>T p.G71= | Silent (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- TXLNB | c.1194G>T p.L398= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100624909; called by muse, mutect2, varscan2
- VAT1L | c.591G>T p.V197= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100213314; called by muse, mutect2, varscan2
- ZFHX4 | c.9303C>A p.L3101= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs552401574, COSV99260953; called by muse, mutect2, varscan2
- ZNF99 | c.1092T>A p.T364= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV101233783; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825205 G>C | 5'Flank (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- CD200R1 | c.68-16750C>A | Intron (SNP) | VAF 9/31 reads (29%) | catalogued as COSV55602521, COSV99867046; called by muse, mutect2, varscan2
- KLK2 | c.630+37G>T | Intron (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100319904; called by muse, mutect2, varscan2
- PARGP1 | n.1713T>C | RNA (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RGS8 | c.-1T>C | 5'UTR (SNP) | VAF 24/93 reads (26%) | catalogued as COSV99276578; called by muse, mutect2, varscan2
- SNORD115-11 | n.71A>G | RNA (SNP) | VAF 98/343 reads (29%) | catalogued as rs1387534534; called by muse, mutect2, varscan2
- SSPOP | n.8657G>T | RNA (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100947230; called by muse, mutect2, varscan2
